Somatic mutation profile of tumor specimen 0DJM8Z from CCDI case PBBWVP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.5 years (1,991 days).
Specimen 0DJM8Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41779208-870b-40ba-94cc-10ff1a869612.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/915cefb6-2484-42cf-8e82-f27e69acb499

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 486/1830 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- HACD1 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 148/394 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.349); called by muse, varscan2
- PRICKLE2 | c.2197G>C p.D733H (on ENST00000295902; = p.D677H on NM_198859.4) | Missense Mutation (SNP) | VAF 298/845 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); called by muse, varscan2
- SERPINE2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 242/710 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANKS1A | c.3402-20dup | Intron (INS) | VAF 119/351 reads (34%) | called by pindel, varscan2
